Somatic mutation profile of tumor specimen TCGA-EE-A184-06A (aliquot TCGA-EE-A184-06A-11D-A196-08) from TCGA case TCGA-EE-A184, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.7 years (28,364 days).
Specimen TCGA-EE-A184-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb2d8f64-811a-49ae-b4e1-0352c0af6b64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A184-10B (Blood Derived Normal), aliquot TCGA-EE-A184-10B-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac03fd8d-3cb5-4811-9aa9-b843b6e51b56

The open-access MAF lists 317 somatic variants for this specimen: 222 protein-altering or splice-affecting, 86 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 86, Nonsense Mutation 17, Splice Site 7, Intron 6, Splice Region 4, RNA 2, Frame Shift Ins 1, Nonstop Mutation 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 95/110 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC39A14 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as rs879253764, CM166809, COSV51485895; ClinVar: pathogenic; called by muse, varscan2
- ACSM3 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as COSV56843031; called by mutect2, varscan2
- ADAMTS18 | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51419241; called by mutect2, varscan2
- ADAMTSL3 | c.4504G>A p.G1502R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV54457776; called by muse, mutect2, varscan2
- ADCK5 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV58234589; called by muse, mutect2, varscan2
- ADGRV1 | c.2196T>G p.D732E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67990102; called by muse, mutect2, varscan2
- ADRB2 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60005852; called by muse, mutect2, varscan2
- AGRN | c.1738C>A p.L580M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65071033; called by muse, mutect2, varscan2
- AKNA | c.2315C>A p.P772Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV56313799; called by mutect2, varscan2
- ALG3 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs999161669, COSV61080604; called by muse, mutect2, varscan2
- ALK | c.3599C>T p.A1200V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs200585833, COSV66556426; ClinVar: uncertain significance; called by mutect2, varscan2
- ANK3 | c.5787C>A p.F1929L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.182); catalogued as rs749828001, COSV55069212; called by muse, varscan2
- ANKDD1A | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as rs765949109, COSV100132823, COSV60353772; called by mutect2, varscan2
- ANKRD13A | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99923835; called by mutect2, varscan2
- ANKRD17 | c.5287A>G p.K1763E | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58224058; called by muse, mutect2, varscan2
- ASPG | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV101496341; called by mutect2, varscan2
- BTBD8 | c.1014C>A p.C338* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV61547101; called by muse, mutect2, varscan2
- C6orf15 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.243); catalogued as rs547282944, COSV52538628; called by muse, mutect2, varscan2
- C9 | c.535G>T p.G179* | Nonsense Mutation (SNP) | VAF 66/383 reads (17%) | catalogued as COSV54676126, COSV54678955; called by muse, mutect2, varscan2
- CA10 | c.987G>T p.*329Yext*11 | Nonstop Mutation (SNP) | VAF 106/179 reads (59%) | catalogued as COSV53359812; called by muse, mutect2, varscan2
- CACYBP | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs780696971, COSV62880510; called by mutect2, varscan2
- CASS4 | c.356G>T p.W119L | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV64387406; called by mutect2, varscan2
- CCDC62 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53435622, COSV53436719; called by mutect2, varscan2
- CDH26 | c.1859C>A p.P620H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV54850261; called by mutect2, varscan2
- CDO1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51665836; called by mutect2, varscan2
- CEACAM19 | c.702T>G p.D234E | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62552166; called by muse, mutect2, varscan2
- CELSR3 | c.2191C>A p.H731N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as COSV50925662; called by mutect2, varscan2
- CERK | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 25/399 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53452372; called by muse, mutect2
- CFAP94 | c.496C>T p.Q166* (on ENST00000320267 / NM_001352064.2; = p.Q172* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100208902; called by muse, mutect2, varscan2
- CFH | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); catalogued as COSV66410760; called by muse, varscan2
- CGA | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63644694; called by mutect2, varscan2
- CHST9 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as rs750559823, COSV52443274; called by mutect2, varscan2
- CLDN17 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54523663, COSV54523848; called by muse, mutect2, varscan2
- CLDN8 | c.604C>A p.H202N | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1344775322, COSV54526532; called by mutect2, varscan2
- CNGB3 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV60693752; called by mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, varscan2
- COL11A2 | c.1871C>A p.P624H (on ENST00000341947 / NM_080680.3; = p.P517H on NM_080679.2) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV59499540; called by mutect2, varscan2
- COL19A1 | c.874-1G>T p.X292_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV59579160; called by mutect2, varscan2
- COL27A1 | c.1529C>A p.P510Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61928569; called by mutect2, varscan2
- CPZ | c.1295G>T p.R432M (on ENST00000360986 / NM_001014447.3; = p.R421M on NM_003652.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs778856137, COSV59924254, COSV59926025; called by mutect2, varscan2
- CR1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs753042039, COSV65460285; called by mutect2, varscan2
- CRACR2B | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100351927; called by mutect2, varscan2
- CSMD1 | c.9527C>T p.S3176F (on ENST00000520002; = p.S3175F on NM_033225.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59350668; called by muse, mutect2, varscan2
- CTSS | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 86/141 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64566658; called by muse, varscan2
- CWH43 | c.1298G>T p.W433L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56941267; called by mutect2, varscan2
- CYP27C1 | c.958G>T p.G320W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58867342, COSV58867409; called by mutect2, varscan2
- CYP4F12 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV61175172; called by mutect2, varscan2
- DDX10 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV100489046; called by muse, mutect2, varscan2
- DGKQ | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs570641266, COSV56618465; called by mutect2, varscan2
- DGKZ | c.1134G>T p.K378N (on ENST00000454345 / NM_001105540.2; = p.K190N on NM_003646.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551044; called by mutect2, varscan2
- DNAH2 | c.10849C>A p.L3617M | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66722489; called by muse, mutect2, varscan2
- DNAH5 | c.10859G>A p.R3620Q | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs547014532, COSV54205387, COSV54209411; called by mutect2, varscan2
- DNAH9 | c.4252G>A p.D1418N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs1310896045, COSV52361497, COSV52372685; called by muse, mutect2, varscan2
- DNAJC25 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100543311; called by mutect2, varscan2
- EFCAB6 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV53067473; called by mutect2, varscan2
- EIF3B | c.2238G>T p.L746F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as COSV100703482, COSV62804039; called by mutect2, varscan2
- EIF5 | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV53686095; called by mutect2, varscan2
- EPHB2 | c.2353-1G>T p.X785_splice (on ENST00000400191 / NM_001309193.2; = p.X786_splice on NM_004442.7) | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV65864173; called by mutect2, varscan2
- EPS8 | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.452); catalogued as COSV55533664; called by mutect2, varscan2
- ETV6 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV67151962; called by muse, mutect2, varscan2
- FAF1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV65641141; called by mutect2, varscan2
- FAM117B | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57418010, COSV57420541; called by mutect2, varscan2
- FAM20A | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV56837494; called by mutect2, varscan2
- FBXO10 | c.2111G>T p.W704L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV52832861; called by mutect2, varscan2
- FCGR3B | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 93/140 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.311); catalogued as COSV54210913; called by mutect2, varscan2
- FGFR2 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV60652930; called by muse, varscan2
- FOXA3 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56216781; called by mutect2, varscan2
- FOXRED1 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55006815, COSV55007779; called by mutect2, varscan2
- FRAS1 | c.9010G>A p.E3004K | Missense Mutation (SNP) | VAF 135/236 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470070058, COSV53627571; called by muse, mutect2, varscan2
- FREM2 | c.4967C>A p.P1656H | Missense Mutation (SNP) | VAF 32/479 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54844119; called by muse, mutect2
- GALNT13 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV67229406; called by muse, mutect2, varscan2
- GALNT15 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60218401; called by mutect2, varscan2
- GGT7 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs916894438, COSV60541721; called by muse, mutect2, varscan2
- GGT7 | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV60541725; called by mutect2, varscan2
- GLI2 | c.1345G>T p.E449* (on ENST00000361492 / NM_001374353.1; = p.E466* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/107 reads (34%) | catalogued as COSV58046396; called by mutect2, varscan2
- GON4L | c.6152T>C p.F2051S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV99673270; called by muse, mutect2, varscan2
- GSAP | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57531436; called by mutect2, varscan2
- HDAC10 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs560148776, COSV50556353, COSV50561141; called by muse, varscan2
- HDAC10 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV50561142; called by muse, varscan2
- HDAC3 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.325); catalogued as COSV51838017; called by mutect2, varscan2
- HELQ | c.2396C>A p.T799N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV55026320; called by muse, mutect2, varscan2
- HNRNPA3 | c.114T>A p.F38L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV66821022; called by mutect2, varscan2
- IGDCC4 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61538137; called by mutect2, varscan2
- IGSF5 | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66030885; called by mutect2, varscan2
- IL37 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54490581, COSV54492118; called by mutect2, varscan2
- INTS8 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100569119; called by muse, mutect2, varscan2
- ITGA7 | c.769C>A p.R257S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57697841, COSV57700762; called by muse, mutect2, varscan2
- ITGAX | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51646062, COSV51648324; called by muse, mutect2, varscan2
- ITGB4 | c.3265G>T p.G1089W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52329534; called by mutect2, varscan2
- JUP | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1555602004, COSV60278995; called by mutect2, varscan2
- KANSL1 | c.2552G>T p.R851M (on ENST00000574590 / NM_001193465.2; = p.R852M on NM_015443.4) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52271156; called by mutect2, varscan2
- KCNT2 | c.2269G>T p.D757Y | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54093033; called by mutect2, varscan2
- KDSR | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100430162; called by mutect2, varscan2
- KERA | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.123); catalogued as COSV57131237; called by muse, varscan2
- KIAA0408 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107164; called by mutect2, varscan2
- KIF3B | c.1733G>T p.R578M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65228444; called by mutect2, varscan2
- KIF4A | c.3612G>T p.K1204N | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV65533615; called by mutect2, varscan2
- KLRC2 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV67900214; called by muse, mutect2, varscan2
- KPRP | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV64222282; called by mutect2, varscan2
- KRT6A | c.1161G>T p.M387I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV58106526; called by mutect2, varscan2
- KRT75 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52873908; called by mutect2, varscan2
- KRT83 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53341288; called by muse, mutect2, varscan2
- KRT85 | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57737523; called by mutect2, varscan2
- KRTAP10-11 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV58178556; called by mutect2, varscan2
- L3MBTL2 | c.1529G>T p.W510L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53434667; called by mutect2, varscan2
- LILRA2 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52194292; called by mutect2, varscan2
- LILRA2 | c.1359G>T p.M453I (on ENST00000391738 / NM_001130917.3; = p.M436I on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV99252728; called by mutect2, varscan2
- LRP1 | c.3176C>A p.P1059H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54518205; called by mutect2, varscan2
- LRRC52 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV54232876; called by mutect2, varscan2
- LTBP2 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000800, COSV56214876; called by mutect2, varscan2
- MAN1B1 | c.1309G>T p.G437W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478434297, COSV100857286, COSV65371088; called by mutect2, varscan2
- MAP1S | c.2146G>T p.G716W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1017076804, COSV60722101, COSV60723582; called by mutect2, varscan2
- MAPK1IP1L | c.-6G>T | Splice Region (SNP) | VAF 28/71 reads (39%) | catalogued as COSV59461125; called by muse, mutect2, varscan2
- MARK1 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100856971, COSV65069416; called by muse, mutect2, varscan2
- MECOM | c.746G>A p.G249E (on ENST00000468789 / NM_001105078.4; = p.G437E on NM_004991.4) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52969254; called by muse, varscan2
- MMP28 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs1326416466; called by mutect2, varscan2
- MROH5 | c.2775C>A p.P925= | Splice Region (SNP) | VAF 5/11 reads (45%) | catalogued as COSV71302255; called by mutect2, varscan2
- MUC4 | c.13664C>A p.P4555H (on ENST00000463781 / NM_018406.7; = p.P319H on NM_004532.6) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV57791025; called by mutect2, varscan2
- MYH10 | c.3430T>G p.L1144V | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52605730; called by muse, mutect2, varscan2
- MYH11 | c.2147C>A p.P716H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100259512, COSV55561071; called by mutect2, varscan2
- MYO18A | c.2259G>T p.E753D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV62870131; called by mutect2, varscan2
- MYO6 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV64120103; called by muse, mutect2, varscan2
- MYOC | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1280400300, COSV50676231; called by muse, mutect2, varscan2
- NCAPH | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV53637453; called by mutect2, varscan2
- NDST3 | c.2264G>T p.W755L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV56623847; called by mutect2, varscan2
- NFKB1 | c.1375G>T p.G459W (on ENST00000394820 / NM_001382627.1; = p.G460W on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV56958993; called by mutect2, varscan2
- NIBAN1 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62286307; called by muse, mutect2, varscan2
- NLRP3 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100276769, COSV60228382; called by mutect2, varscan2
- NOL12 | c.382-1G>T p.X128_splice | Splice Site (SNP) | VAF 23/249 reads (9%) | catalogued as COSV63031407; called by muse, mutect2
- NOTCH3 | c.5542C>A p.R1848S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54640321, COSV54641237; called by muse, mutect2, varscan2
- NOX5 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52988722, COSV52992647; called by mutect2, varscan2
- NPAS4 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60651563; called by muse, mutect2, varscan2
- NR3C2 | c.2220G>T p.M740I | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60995426; called by muse, varscan2
- NUP205 | c.3727C>A p.L1243I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as COSV53662779; called by muse, mutect2, varscan2
- NUP210 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54409633; called by muse, mutect2, varscan2
- NWD1 | c.2829G>T p.Q943H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV60346547; called by mutect2, varscan2
- NXF3 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67704410; called by muse, mutect2, varscan2
- OAS3 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs201783757; called by muse, varscan2
- ODF2L | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV54016711; called by muse, mutect2, varscan2
- OR10T2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100554809, COSV57783375; called by muse, mutect2, varscan2
- OR13C5 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV101053007; called by mutect2, varscan2
- OR13C9 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV52242859; called by mutect2, varscan2
- OR4C16 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1452991979, COSV58943027; called by mutect2, varscan2
- OR51A4 | c.869C>A p.P290Q | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66749790; called by mutect2, varscan2
- OR52E6 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV61432640; called by muse, mutect2, varscan2
- OR52J3 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV66747387; called by mutect2, varscan2
- OSMR | c.1886C>G p.P629R | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57088176; called by muse, varscan2
- PCDH1 | c.3250C>A p.L1084M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54616806; called by mutect2, varscan2
- PCDH19 | c.2016G>T p.M672I | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55267087; called by muse, mutect2, varscan2
- PCDHA7 | c.981C>A p.F327L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV65345755; called by mutect2, varscan2
- PCDHB4 | c.2339G>T p.R780M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV52024511; called by mutect2, varscan2
- PCK2 | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53749757; called by mutect2, varscan2
- PCLO | c.7883C>A p.A2628D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV61649487; called by muse, mutect2, varscan2
- PEG3 | c.1213C>A p.H405N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55640130; called by muse, mutect2, varscan2
- PEG3 | c.872C>A p.T291N | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV55640140; called by muse, mutect2, varscan2
- PIWIL1 | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV55349406; called by mutect2, varscan2
- PLIN3 | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV55736050; called by mutect2, varscan2
- PNMA3 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as rs201029233, COSV64722654; called by mutect2, varscan2
- PRSS21 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50051767; called by mutect2, varscan2
- PTGIS | c.1499C>A p.P500Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54838833; called by mutect2, varscan2
- PTPRT | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761753488, COSV61998693; called by mutect2, varscan2
- RAET1G | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV66274835; called by mutect2, varscan2
- RAPH1 | c.2486C>A p.P829H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55586519; called by mutect2, varscan2
- RELT | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV50360938, COSV50361914; called by muse, mutect2, varscan2
- RGS12 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60907598; called by mutect2, varscan2
- RIBC1 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV99394849; called by muse, mutect2, varscan2
- RICTOR | c.1419G>C p.L473F | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV57126092; called by muse, mutect2, varscan2
- ROS1 | c.6885G>T p.Q2295H | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV63858319; called by mutect2, varscan2
- SCAPER | c.3845C>A p.P1282Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV57746237; called by mutect2, varscan2
- SHC3 | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV65446566; called by muse, mutect2, varscan2
- SI | c.3371G>T p.R1124L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV52289170, COSV52303078; called by muse, mutect2, varscan2
- SLC25A34 | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV53817749; called by mutect2, varscan2
- SLC27A3 | c.859G>T p.G287* (on ENST00000271857; = p.G159* on NM_024330.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55164674; called by mutect2, varscan2
- SLC7A10 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1452758428, COSV53505769; called by muse, mutect2, varscan2
- SLC8A3 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63523816; called by muse, mutect2, varscan2
- SLIT2 | c.3383T>C p.F1128S | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV56582815; called by muse, mutect2, varscan2
- SLIT3 | c.1832T>G p.M611R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60621210; called by muse, mutect2, varscan2
- SMC1B | c.1067A>C p.E356A | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV62531686; called by muse, mutect2, varscan2
- SNRPA | c.601-1G>A p.X201_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54681947; called by muse, mutect2, varscan2
- SPOCK1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as rs1480478097, COSV56456542; called by muse, varscan2
- SPOCK3 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV62731006; called by mutect2, varscan2
- SPRR2B | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as COSV100482233; called by mutect2, varscan2
- SYN3 | c.1095G>A p.E365= | Splice Region (SNP) | VAF 11/79 reads (14%) | catalogued as COSV60511898; called by muse, mutect2, varscan2
- TAB1 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as COSV53372244; called by muse, mutect2, varscan2
- TAS2R39 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV71470940; called by mutect2, varscan2
- TATDN1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV52679859, COSV52680841; called by mutect2, varscan2
- TCEA3 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs777318907, COSV71532059; called by mutect2, varscan2
- TCERG1L | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as COSV64053002; called by mutect2, varscan2
- TCHH | c.2952G>T p.Q984H | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); catalogued as COSV64276229; called by muse, mutect2, varscan2
- TENM4 | c.7930G>T p.G2644W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776302209, COSV53647521; called by mutect2, varscan2
- TENT5C | c.935G>T p.R312M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV65616675; called by mutect2, varscan2
- TERT | c.2254C>A p.H752N | Missense Mutation (SNP) | VAF 75/486 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV57227056; called by mutect2, varscan2
- TMEM198 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV54725103; called by mutect2, varscan2
- TMPRSS15 | c.2824C>A p.Q942K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV53043716; called by muse, varscan2
- TNIP1 | c.358-1G>T p.X120_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV59308606; called by muse, mutect2, varscan2
- TNRC6B | c.4171G>T p.G1391* (on ENST00000454349 / NM_001162501.2; = p.G1281* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 60/87 reads (69%) | catalogued as COSV57301445; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV50556060; called by mutect2, varscan2
- TRIM69 | c.677G>T p.R226L (on ENST00000329464 / NM_182985.5; = p.R67L on NM_080745.5) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57804149, COSV57804512; called by muse, mutect2, varscan2
- TRNAU1AP | c.246C>A p.N82K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV65778174; called by muse, mutect2, varscan2
- TSPAN12 | c.150-1G>T p.X50_splice | Splice Site (SNP) | VAF 36/104 reads (35%) | catalogued as COSV56080717; called by mutect2, varscan2
- TTN | c.68998G>T p.E23000* (on ENST00000591111; = p.E15576* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100597238, COSV60189867; called by mutect2, varscan2
- TTN | c.22265G>A p.R7422Q (on ENST00000591111; = p.R6495Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | PolyPhen benign (0.333); catalogued as rs749882000, COSV59960172; called by mutect2, varscan2
- TUBB6 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV52315965; called by mutect2, varscan2
- TULP3 | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV68118314; called by mutect2, varscan2
- TUT7 | c.4202G>T p.R1401M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs76212915, COSV52897172; called by muse, mutect2, varscan2
- UFM1 | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs759243065, COSV53495951; called by mutect2, varscan2
- USP29 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV54144522; called by mutect2, varscan2
- VSIR | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141431398; called by muse, mutect2, varscan2
- ZNF300 | c.1579G>T p.G527W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV51041250; called by mutect2, varscan2
- ZNF425 | c.1873C>A p.L625M | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); catalogued as COSV65201910; called by mutect2, varscan2
- ZNF492 | c.1151A>C p.K384T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV71762168; called by mutect2, varscan2
- ZNF514 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.888); catalogued as COSV54634754; called by muse, mutect2, varscan2
- ZNF577 | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs200513224, COSV56814846, COSV56816943; called by mutect2, varscan2
- ZZEF1 | c.6157G>T p.G2053* | Nonsense Mutation (SNP) | VAF 32/44 reads (73%) | catalogued as COSV67558823; called by mutect2, varscan2
- AP3B1 | c.224dup p.N75Kfs*4 | Frame Shift Ins (INS) | VAF 74/227 reads (33%) | called by pindel, varscan2
- FCGBP | c.2872G>T p.G958W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- IGKV2D-28 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by mutect2, varscan2
- KIR3DL3 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRCIN1 | c.2347C>A p.H783N (on ENST00000621492; = p.H749N on NM_025248.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.275); called by mutect2, varscan2
- SYMPK | c.2152_2154del p.L718del | In Frame Del (DEL) | VAF 8/37 reads (22%) | called by pindel, varscan2
- TUBGCP5 | c.2146T>C p.L716= | Splice Region (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- ABCC8 | c.3702C>T p.N1234= | Silent (SNP) | VAF 100/270 reads (37%) | catalogued as COSV56854022; called by mutect2, varscan2
- ARHGAP45 | c.3024G>T p.V1008= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV53124678; called by muse, mutect2, varscan2
- ARMCX1 | c.315G>A p.E105= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV65705354; called by muse, mutect2, varscan2
- ATP8B2 | c.51C>A p.S17= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as COSV59247329; called by mutect2, varscan2
- ATRN | c.2187C>A p.P729= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV53530750; called by mutect2, varscan2
- BCAR1 | c.1812C>A p.L604= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV50791177; called by mutect2, varscan2
- CACNA1C | c.6189C>T p.C2063= (on ENST00000399634 / NM_001167625.1; = p.C1992= on NM_000719.7) | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs369690952; called by mutect2, varscan2
- CACNA1E | c.3651C>T p.Y1217= | Silent (SNP) | VAF 82/323 reads (25%) | catalogued as COSV62405912; called by muse, mutect2, varscan2
- CASP10 | c.429C>A p.P143= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53778988, COSV99628709; called by muse, mutect2, varscan2
- CCKBR | c.1251C>A p.P417= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV58101358, COSV58103429; called by mutect2, varscan2
- CD37 | c.810G>T p.L270= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV60544890; called by mutect2, varscan2
- CLP1 | c.522C>A p.V174= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57055119; called by muse, mutect2, varscan2
- CORO1A | c.57C>A p.A19= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV54631647; called by mutect2, varscan2
- CRISP3 | c.489C>A p.P163= (on ENST00000371159 / NM_001368123.1; = p.P145= on NM_006061.4) | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV53821829; called by mutect2, varscan2
- CRTC1 | c.1461G>A p.A487= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs775882136, COSV58720991; called by mutect2, varscan2
- CSPG4 | c.2208G>T p.V736= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV57898539; called by muse, mutect2, varscan2
- CUX1 | c.3306C>A p.P1102= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV52906862; called by mutect2, varscan2
- DCAF1 | c.588C>A p.P196= | Silent (SNP) | VAF 104/224 reads (46%) | catalogued as COSV60044832; called by muse, mutect2, varscan2
- DMRTA1 | c.153C>A p.P51= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV57924775; called by mutect2, varscan2
- DNAH17 | c.2580G>A p.K860= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs749133374, COSV67758328; called by muse, mutect2, varscan2
- EGFR | c.3288C>A p.S1096= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV51821974; called by muse, mutect2, varscan2
- ELFN2 | c.1398C>A p.P466= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV68743926, COSV68745375; called by muse, mutect2, varscan2
- ELN | c.168G>T p.L56= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV52712735; called by mutect2, varscan2
- EXOSC7 | c.846C>A p.P282= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs140279197; called by mutect2, varscan2
- FAHD1 | c.615C>A p.I205= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV66900225; called by muse, mutect2, varscan2
- FANCD2 | c.3378C>A p.P1126= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as COSV55041848; called by muse, mutect2, varscan2
- FGFBP2 | c.516G>T p.L172= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV52588285; called by mutect2, varscan2
- FOXN3 | c.1338C>A p.P446= (on ENST00000261302; = p.P424= on NM_005197.4) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV54312941; called by muse, mutect2, varscan2
- GAD2 | c.318C>A p.P106= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV52162724; called by mutect2, varscan2
- GLB1L2 | c.1083T>C p.L361= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV60279576; called by muse, varscan2
- GRID2 | c.717C>A p.A239= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV99937265; called by mutect2, varscan2
- GRIN2A | c.2973C>T p.S991= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58045284; called by muse, mutect2, varscan2
- HERC2 | c.294G>T p.L98= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV55336136; called by mutect2, varscan2
- HK3 | c.2277C>T p.I759= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs369639684; called by mutect2, varscan2
- IGHV3-20 | c.126A>C p.A42= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1555454756; called by muse, mutect2, varscan2
- IGLV3-1 | c.246C>T p.G82= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs532150377; called by mutect2, varscan2
- IQCN | c.2343C>A p.S781= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as rs779045521, COSV66575656; called by mutect2, varscan2
- IRF2BP1 | c.420G>T p.L140= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV56194351; called by mutect2, varscan2
- ISX | c.504C>A p.P168= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as COSV58087655; called by mutect2, varscan2
- JAKMIP2 | c.1341A>C p.S447= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV54609561; called by muse, mutect2, varscan2
- JUP | c.2130C>T p.P710= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV60278989; called by muse, mutect2, varscan2
- KANSL2 | c.936C>A p.S312= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs945938594, COSV63480027; called by mutect2, varscan2
- KCNB1 | c.2058C>A p.P686= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV65569598; called by muse, mutect2, varscan2
- KCNJ1 | c.931C>A p.R311= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as CM994547, COSV60661865, COSV60662273; called by muse, mutect2, varscan2
- KDR | c.1629C>A p.I543= | Silent (SNP) | VAF 117/333 reads (35%) | catalogued as COSV99816703; called by mutect2, varscan2
- KIAA1549 | c.1326G>T p.V442= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV54320799; called by mutect2, varscan2
- KRTAP12-2 | c.276C>A p.P92= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV59970485; called by mutect2, varscan2
- LAIR1 | c.318C>A p.P106= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV57308615; called by muse, mutect2, varscan2
- LATS2 | c.3084C>A p.P1028= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV66877657; called by muse, mutect2, varscan2
- LRIT2 | c.1239C>A p.P413= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV60564453; called by muse, mutect2, varscan2
- MCM7 | c.1644C>A p.P548= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100384600, COSV57996372; called by mutect2, varscan2
- MRPS35 | c.93G>T p.P31= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV50011817; called by muse, mutect2, varscan2
- MYCL | c.594C>A p.P198= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV65693533; called by mutect2, varscan2
- NEFM | c.306G>A p.K102= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55333397; called by muse, mutect2, varscan2
- NKX3-2 | c.384G>T p.P128= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV66711861; called by mutect2, varscan2
- NLRP3 | c.2580G>T p.V860= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs1294489789, COSV60228390; called by mutect2, varscan2
- NOMO1 | c.2391G>T p.G797= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV55059989; called by mutect2, varscan2
- NR4A1 | c.498T>G p.T166= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV54485081; called by muse, mutect2, varscan2
- OGFOD3 | c.624C>A p.P208= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV57341996; called by mutect2, varscan2
- OR51B5 | c.253C>T p.L85= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1218953607, COSV56176705; called by muse, mutect2, varscan2
- OR5M10 | c.324G>T p.V108= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV73242374, COSV73242378; called by mutect2, varscan2
- PLA2G4D | c.1971C>A p.P657= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV51822193; called by mutect2, varscan2
- PPIAL4G | c.372C>A p.G124= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV70087305; called by muse, mutect2, varscan2
- PRR13 | c.411C>A p.S137= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as COSV65769180; called by muse, mutect2, varscan2
- PSD | c.246C>A p.P82= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV50050414; called by mutect2, varscan2
- RASSF10 | c.1155G>T p.L385= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV61754583; called by mutect2, varscan2
- RGR | c.504G>A p.L168= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV63894725; called by muse, mutect2, varscan2
- RIMS4 | c.198C>A p.S66= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs1325783975, COSV65720178; called by mutect2, varscan2
- RNF146 | c.192T>G p.A64= (on ENST00000368314 / NM_001242850.2; = p.A63= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV58933328; called by muse, mutect2, varscan2
- RNF213 | c.9825G>T p.L3275= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV60403226; called by mutect2, varscan2
- RYR3 | c.9462C>A p.P3154= (on ENST00000389232; = p.P3155= on NM_001036.6) | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV66800348, COSV66800544; called by muse, mutect2, varscan2
- SARAF | c.891C>A p.P297= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV56357879; called by mutect2, varscan2
- SLC2A1 | c.510C>T p.I170= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs748156710, COSV65287863; called by mutect2, varscan2
- SS18L1 | c.549C>T p.S183= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV59211890; called by muse, mutect2, varscan2
- STOX2 | c.2695C>A p.R899= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57854065; called by muse, mutect2, varscan2
- SUGP2 | c.3042G>T p.L1014= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58261817; called by mutect2, varscan2
- SUPT6H | c.4758C>A p.S1586= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV56387793; called by mutect2, varscan2
- TET3 | c.2013C>A p.P671= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV59881866; called by mutect2, varscan2
- TRAF3IP3 | c.111C>A p.P37= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV50556019; called by mutect2, varscan2
- TRPC4 | c.2526C>T p.I842= (on ENST00000379705 / NM_016179.4; = p.I847= on NM_003306.3) | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs762999927, COSV59007746; called by mutect2, varscan2
- TTN | c.8988C>A p.G2996= (on ENST00000591111; = p.G2950= on NM_003319.4) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100593845; called by muse, mutect2, varscan2
- UBAP2L | c.2007C>A p.T669= | Silent (SNP) | VAF 118/172 reads (69%) | catalogued as rs1372796849, COSV55176895; called by muse, mutect2, varscan2
- VWA1 | c.711C>T p.T237= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs371003158; called by muse, mutect2, varscan2
- WWP2 | c.546C>A p.P182= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV63124525, COSV63126179; called by mutect2, varscan2
- ZBED6CL | c.154T>C p.L52= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV59605031; called by muse, mutect2, varscan2
- ZNF462 | c.1326C>A p.P442= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV52945689; called by mutect2, varscan2
- CDC37P1 | n.342G>T | RNA (SNP) | VAF 45/55 reads (82%) | called by mutect2, varscan2
- CHD3 | c.4358+212T>C | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100390680; called by muse, mutect2, varscan2
- CHD3 | c.4358+213C>T | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs770652523, COSV57874045; called by muse, mutect2, varscan2
- FGFR2 | c.939+1239C>A | Intron (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100335338; called by mutect2, varscan2
- GH2 | c.456+9G>T | Intron (SNP) | VAF 29/102 reads (28%) | catalogued as COSV60427318; called by mutect2, varscan2
- LINC01565 | n.1055C>A | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- PLVAP | c.*2G>T | 3'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99391473; called by mutect2, varscan2
- PML | c.1710+882G>A | Intron (SNP) | VAF 27/67 reads (40%) | catalogued as rs756641826, COSV51449852; called by mutect2, varscan2
- SPTBN4 | c.5915+34C>A | Intron (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100149988; called by muse, mutect2, varscan2
